Surgical pathology report (de-identified scan), TCGA case TCGA-2Z-A9JT, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site Moffitt Cancer Center, specimen TCGA-2Z-A9JT-01A (Primary Tumor).

[page 1 of 2]
Pathology Report

Final Diagnosis

- A. DEEP MARGIN RIGHT KIDNEY:
Benign renal parenchyma.
- B. RIGHT KIDNEY, PARTIAL NEPHRECTOMY
Renal cell carcinoma, papillary type II. See Key Pathologic Findings.
Surgical margins, free of malignancy.
Pathologic stage: pT1a NX MX.
- C. ADDITIONAL RIGHT CYSTIC WALL:
Benign adipose tissue.

I, _____ the attending pathologist, personally reviewed all slides and / or materials and rendered the final diagnosis. Electronically Signed Out by

Key Pathological Findings

PROCEDURE:

Partial nephrectomy

SPECIMEN LATERALITY:

Right

TUMOR SIZE (largest tumor if multiple):

Dimension: 2.9 cm

TUMOR FOCALITY:

Unifocal

MACROSCOPIC EXTENT OF TUMOR:

Tumor limited to kidney

HISTOLOGIC TYPE:

Papillary renal cell carcinoma

SARCOMATOID FEATURES:

Not identified

TUMOR NECROSIS:

Present 10 %

HISTOLOGIC GRADE (Fuhrman Nuclear Grade):

G3: Nuclei very irregular, approximately 20 microns; nucleoli large and prominent

MICROSCOPIC TUMOR EXTENSION:

Tumor limited to kidney

MARGINS:

Margins uninvolved by carcinoma

PERINEURAL INVASION:

Absent

ANGIOLYMPHATIC INVASION:

Absent

LYMPH-VASCULAR INVASION:

Absent

PRIMARY TUMOR (pT):

pT1a: Tumor 4 cm or less in greatest dimension, limited to the kidney

ICD O-3
Carcinoma, papillary renal
cell 8260/3
Site: R Kidney NOS C64.9
JW 4/28/14

[page 2 of 2]
REGIONAL LYMPH NODES (pN):

pNX: Regional lymph nodes cannot be assessed

DISTANT METASTASIS (pM):

pMX

Specimen(s) Received

- A DEEP MARGIN RIGHT KIDNEY FS
- B RIGHT PARTIAL NEPHRECTOMY
- C ADDITIONAL RIGHT CYSTIC WALL

Clinical History

History of prostate cancer

Preoperative Diagnosis

Renal mass

Intraoperative Consultation

FSA1. DEEP MARGIN RIGHT KIDNEY:

No tumor identified.

Comment: This frozen section diagnosis/result was communicated to and acknowledged by Dr.

I, _____ have performed the intraoperative consultation and issued the above diagnosis.

Gross Description

A. The specimen is received fresh for frozen section consult, labeled "deep margin right kidney." The specimen consists of an unoriented, red-tan, rubbery fragment of renal tissue, 0.6 x 0.5 x 0.3 cm. The specimen is submitted entirely intact in FSA1.

The specimen is not submitted for Tissue Procurement Laboratory.

B. The specimen is received fresh, labeled "right partial nephrectomy" and consists of an unoriented, encapsulated, rubbery nodule, 7.5 grams, 2.9 x 2.8 x 2.2 cm. The capsule is intact with focal adhesions, and inked black. Sectioned, the cut surfaces exhibit dark tan, smooth, congested spongy tissue with glistening surfaces, comprising the entire specimen. Normal renal parenchyma is not identified. The tissue extends to the capsule, however, does not extend through. Necrosis up to 10% is noted with focal hemorrhage. Representative sections are submitted in B1-B4.

The specimen is submitted to Tissue Procurement Laboratory, as reflected in cassette B4.

C. The specimen is received fresh, labeled "additional right cystic wall." The specimen consists of an unoriented, pale white, soft fatty tissue, 7 mm. The specimen is submitted entirely intact in C1.

The specimen is not submitted for Tissue Procurement Laboratory.

Source: NCI Genomic Data Commons file 67d95f3f-abc1-4878-9d67-931b3dd91a18 (TCGA-2Z-A9JT.9A3E09B9-414B-4791-8F75-FF33EB6A5D6F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).